Somatic mutation profile of tumor specimen 0DVKDZ from CCDI case PBCMZN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.2 years (5,913 days).
Specimen 0DVKDZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a157f70f-eb0e-4036-bb02-0013d7c85712.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVKEI (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c07afee8-a83e-4a2d-9d78-8fd0fbc06439

The open-access MAF lists 20 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 5, Intron 5, 3'UTR 4, Silent 3, Missense Mutation 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KISS1 | c.240C>A p.S80R | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- MFSD4A | c.93C>A p.C31* | Nonsense Mutation (SNP) | VAF 12/239 reads (5%) | called by muse, mutect2
- ZNF674 | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.553); called by muse, mutect2
- EHD3 | c.1557C>T p.N519= | Silent (SNP) | VAF 104/498 reads (21%) | catalogued as rs151181600; called by muse, mutect2, varscan2
- LRRC24 | c.906C>A p.G302= | Silent (SNP) | VAF 16/367 reads (4%) | called by muse, mutect2
- ZNF83 | c.1059C>A p.V353= | Silent (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- CAV1 | c.*88C>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- COMMD4 | c.*56C>A | 3'UTR (SNP) | VAF 18/280 reads (6%) | called by muse, mutect2
- DECR2 | c.202-30C>A | Intron (SNP) | VAF 7/92 reads (8%) | called by muse, mutect2
- EFCAB14 | c.-55C>A | 5'UTR (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- GXYLT2 | c.-87C>A | 5'UTR (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- LORICRIN | c.*23C>A | 3'UTR (SNP) | VAF 12/354 reads (3%) | called by muse, mutect2
- MAN2B2 | c.2932+67C>A | Intron (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- MRPL3 | c.-44C>A | 5'UTR (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- NREP | c.-79C>A | 5'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2, varscan2
- PDHA1 | c.*1995G>T | 3'UTR (SNP) | VAF 4/24 reads (17%) | called by muse, varscan2
- SLC38A5 | c.130-49C>A | Intron (SNP) | VAF 5/46 reads (11%) | called by muse, mutect2
- SMARCD3 | c.1398+91C>A | Intron (SNP) | VAF 5/68 reads (7%) | called by muse, mutect2
- TMEM63A | c.2251-95C>A | Intron (SNP) | VAF 6/83 reads (7%) | called by muse, mutect2
- TTC7A | c.-86C>A | 5'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
